Somatic mutation profile of tumor specimen 0DKJXN from CCDI case PBBYGX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 15.0 years (5,469 days).
Specimen 0DKJXN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7720751f-5f0a-413c-add1-e2f94f34e3d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKJXG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23acfb20-4240-4d95-802b-5c4cd12e8910

The open-access MAF lists 111 somatic variants for this specimen: 61 protein-altering or splice-affecting, 29 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 29, Intron 13, 3'UTR 4, 5'UTR 3, Splice Region 2, Nonsense Mutation 2, Frame Shift Ins 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 405/416 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARL14 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 163/756 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.815); catalogued as rs781128689; called by mutect2, varscan2
- CASR | c.2956G>A p.V986I (on ENST00000490131; = p.V1063I on NM_000388.4) | Missense Mutation (SNP) | VAF 192/1218 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs781635511; called by muse, mutect2, varscan2
- CELSR3 | c.3296A>G p.N1099S | Missense Mutation (SNP) | VAF 123/603 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781612743; called by muse, mutect2, varscan2
- DSG4 | c.2945C>T p.T982M | Missense Mutation (SNP) | VAF 161/636 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs140423185, COSV99077204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSPP | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 203/677 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.74); catalogued as rs1315654306; called by muse, mutect2, varscan2
- EXD3 | c.2530C>A p.H844N | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100573599; called by muse, mutect2
- FCGBP | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 100/257 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.509); catalogued as rs1568356268; called by muse, mutect2, varscan2
- GABRR1 | c.222G>T p.K74N | Missense Mutation (SNP) | VAF 334/1076 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65619522; called by mutect2, varscan2
- GIMAP1 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 117/754 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as COSV56187780; called by muse, mutect2, varscan2
- LILRB4 | c.1243C>T p.R415W (on ENST00000391733 / NM_001278428.3; = p.R414W on NM_001278426.3) | Missense Mutation (SNP) | VAF 27/523 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs753701467; called by muse, mutect2
- MMP15 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 190/422 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs878976337; called by muse, mutect2, varscan2
- OSBPL7 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 181/554 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs143564256; called by muse, mutect2, varscan2
- RAB11B | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 154/628 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.061); catalogued as rs921864727, COSV60085789; called by muse, mutect2, varscan2
- RPS6KB2 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.17); catalogued as COSV57047850; called by muse, mutect2, varscan2
- RSAD1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 324/573 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs745834642; called by muse, mutect2, varscan2
- SRGAP3 | c.3080G>A p.R1027H | Missense Mutation (SNP) | VAF 191/767 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.511); catalogued as rs761196341, COSV64530792, COSV64531243; called by muse, mutect2, varscan2
- STK36 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 190/519 reads (37%) | catalogued as rs367544447; called by muse, mutect2, varscan2
- TMA16 | c.45dup p.V16Sfs*6 | Frame Shift Ins (INS) | VAF 278/958 reads (29%) | catalogued as rs570113265; called by mutect2, varscan2
- TMIGD1 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 38/734 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.371); catalogued as rs768181695, COSV104410407; called by muse, mutect2
- AAK1 | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 201/790 reads (25%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 14/544 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- CDK14 | c.658T>C p.Y220H (on ENST00000380050 / NM_001287135.2; = p.Y202H on NM_012395.3) | Missense Mutation (SNP) | VAF 154/773 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP131 | c.418T>A p.S140T | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.022); called by muse, mutect2
- CFI | c.1700A>C p.D567A | Missense Mutation (SNP) | VAF 235/741 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CSMD3 | c.2798T>A p.I933N (on ENST00000297405 / NM_001363185.1; = p.I829N on NM_052900.3) | Missense Mutation (SNP) | VAF 391/1085 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUL5 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 208/1121 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DICER1 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 209/1034 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- DYNC2I2 | c.929A>C p.E310A | Missense Mutation (SNP) | VAF 135/522 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHB3 | c.2948T>C p.I983T | Missense Mutation (SNP) | VAF 135/694 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- FAM98A | c.404A>C p.Q135P | Missense Mutation (SNP) | VAF 289/1072 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- GMNN | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 139/550 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GUK1 | c.549G>C p.E183D | Missense Mutation (SNP) | VAF 133/480 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEPACAM | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- HTR3A | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 183/923 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- IGSF9B | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 116/683 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ITGAV | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 64/1156 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCNJ8 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 131/783 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLRC2 | c.15A>T p.R5S | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- KLRC3 | c.15A>T p.R5S | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.359); called by mutect2, varscan2
- LRRN2 | c.910T>A p.F304I | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, mutect2
- LYZL1 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 111/870 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MACF1 | c.4414G>C p.E1472Q | Missense Mutation (SNP) | VAF 116/958 reads (12%) | called by muse, mutect2, varscan2
- NTS | c.93A>T p.K31N | Missense Mutation (SNP) | VAF 378/919 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- NUP210L | c.4126G>C p.A1376P | Missense Mutation (SNP) | VAF 94/525 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- OR6C70 | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 200/748 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- PGGHG | c.471-6T>C | Splice Region (SNP) | VAF 107/963 reads (11%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 165/1006 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PRR23C | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 181/620 reads (29%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RTTN | c.3549C>A p.D1183E | Missense Mutation (SNP) | VAF 95/1016 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- SIPA1 | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- SIRPD | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 389/663 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SLIT1 | c.3074G>T p.G1025V | Missense Mutation (SNP) | VAF 169/529 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SS18L1 | c.1092G>C p.Q364H | Missense Mutation (SNP) | VAF 164/819 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TCP10L2 | c.110T>A p.V37D | Missense Mutation (SNP) | VAF 207/689 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- TRPV5 | c.1124A>G p.E375G | Missense Mutation (SNP) | VAF 108/519 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNDC5 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 319/1388 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- USH2A | c.6324A>C p.T2108= | Splice Region (SNP) | VAF 144/441 reads (33%) | called by muse, mutect2, varscan2
- XYLT1 | c.1087-1G>A p.X363_splice | Splice Site (SNP) | VAF 183/304 reads (60%) | called by muse, mutect2, varscan2
- ZNF17 | c.1630C>G p.H544D | Missense Mutation (SNP) | VAF 22/707 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- ZNF33B | c.358A>G p.N120D | Missense Mutation (SNP) | VAF 178/1049 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM2 | c.258A>G p.Q86= | Silent (SNP) | VAF 184/1309 reads (14%) | catalogued as COSV55866475; called by muse, mutect2, varscan2
- ARFGEF3 | c.1965T>C p.T655= | Silent (SNP) | VAF 16/548 reads (3%) | called by muse, mutect2
- CATSPERB | c.3036A>C p.S1012= | Silent (SNP) | VAF 311/1001 reads (31%) | called by muse, mutect2, varscan2
- CEP83 | c.1941T>A p.V647= | Silent (SNP) | VAF 47/1700 reads (3%) | called by muse, mutect2
- CRTC1 | c.1767C>T p.F589= | Silent (SNP) | VAF 136/284 reads (48%) | catalogued as rs764408980, COSV58722095; called by muse, mutect2, varscan2
- FLRT1 | c.438G>A p.S146= | Silent (SNP) | VAF 182/501 reads (36%) | catalogued as rs780377796; called by muse, mutect2, varscan2
- FOXL2 | c.711T>A p.G237= | Silent (SNP) | VAF 53/312 reads (17%) | called by muse, mutect2, varscan2
- GNB5 | c.699C>T p.F233= (on ENST00000261837 / NM_016194.4; = p.F191= on NM_006578.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/491 reads (15%) | called by muse, mutect2, varscan2
- ITGA6 | c.1233C>G p.T411= (on ENST00000442250; = p.T372= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 132/1023 reads (13%) | catalogued as COSV51220766; called by muse, mutect2, varscan2
- KIF5A | c.1560T>C p.S520= | Silent (SNP) | VAF 83/351 reads (24%) | called by muse, mutect2, varscan2
- MCMDC2 | c.282G>A p.T94= | Silent (SNP) | VAF 203/1346 reads (15%) | catalogued as rs138140068, COSV58035305; called by muse, mutect2, varscan2
- MTCH1 | c.69A>G p.G23= | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as rs1261265334; called by muse, mutect2, varscan2
- MUC12 | c.11319A>G p.E3773= (on ENST00000379442; = p.E3630= on NM_001164462.1) | Silent (SNP) | VAF 70/2088 reads (3%) | called by muse, mutect2
- OCLN | c.499A>C p.R167= | Silent (SNP) | VAF 60/594 reads (10%) | called by muse, mutect2
- OR11L1 | c.720A>T p.T240= | Silent (SNP) | VAF 176/600 reads (29%) | called by mutect2, varscan2
- OR2Z1 | c.528C>T p.H176= | Silent (SNP) | VAF 147/602 reads (24%) | called by muse, mutect2, varscan2
- PERP | c.291C>T p.F97= | Silent (SNP) | VAF 269/934 reads (29%) | catalogued as rs369663178; called by muse, mutect2, varscan2
- PHF8 | c.1371G>T p.P457= (on ENST00000357988 / NM_001184896.1; = p.P421= on NM_015107.3) | Silent (SNP) | VAF 360/710 reads (51%) | called by muse, mutect2, varscan2
- PIGN | c.2322T>C p.T774= | Silent (SNP) | VAF 246/1527 reads (16%) | catalogued as rs1207646812; called by muse, mutect2, varscan2
- PLCG1 | c.3801C>T p.L1267= (on ENST00000373271 / NM_182811.2; = p.L1268= on NM_002660.3) | Silent (SNP) | VAF 158/1271 reads (12%) | catalogued as rs753162784; called by muse, mutect2, varscan2
- RAI1 | c.1671T>A p.S557= | Silent (SNP) | VAF 128/244 reads (52%) | called by muse, mutect2, varscan2
- RBMXL2 | c.522C>T p.G174= | Silent (SNP) | VAF 2810/3822 reads (74%) | catalogued as rs1316869177; called by mutect2, varscan2
- RWDD2A | c.693A>G p.G231= | Silent (SNP) | VAF 180/658 reads (27%) | called by muse, mutect2, varscan2
- SERPINB7 | c.114C>A p.A38= | Silent (SNP) | VAF 358/1213 reads (30%) | called by mutect2, varscan2
- SETD1B | c.4332C>G p.L1444= | Silent (SNP) | VAF 55/261 reads (21%) | catalogued as COSV57348017; called by muse, mutect2, varscan2
- SFRP2 | c.705G>A p.S235= | Silent (SNP) | VAF 172/589 reads (29%) | catalogued as rs143701440; called by muse, mutect2, varscan2
- TRPC4 | c.2415G>A p.P805= (on ENST00000379705 / NM_016179.4; = p.P810= on NM_003306.3) | Silent (SNP) | VAF 35/1226 reads (3%) | catalogued as rs1386697561, COSV58999429, COSV59001099; called by muse, mutect2
- UHRF1BP1 | c.465C>T p.V155= | Silent (SNP) | VAF 233/858 reads (27%) | catalogued as rs1397825162; called by muse, mutect2, varscan2
- ZNF90 | c.237T>C p.F79= | Silent (SNP) | VAF 146/841 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.1901-14del | Intron (DEL) | VAF 96/412 reads (23%) | called by mutect2, varscan2
- ALDH7A1 | c.1415+52G>C | Intron (SNP) | VAF 79/611 reads (13%) | called by muse, mutect2, varscan2
- CCT5 | chr5:10249986 A>C | 5'Flank (SNP) | VAF 164/1378 reads (12%) | called by muse, mutect2, varscan2
- CYP27C1 | c.*86G>T | 3'UTR (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- DAXX | c.-125T>G | 5'UTR (SNP) | VAF 31/284 reads (11%) | called by muse, mutect2, varscan2
- DCLK1 | c.1035+3743T>C | Intron (SNP) | VAF 247/1392 reads (18%) | called by muse, mutect2, varscan2
- DST | c.4296+3960C>A | Intron (SNP) | VAF 161/764 reads (21%) | called by muse, mutect2, varscan2
- H1-2 | c.*39G>C | 3'UTR (SNP) | VAF 64/254 reads (25%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-711T>C | Intron (SNP) | VAF 119/448 reads (27%) | called by muse, mutect2, varscan2
- LRRC10B | c.-16G>A | 5'UTR (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- MACF1 | c.15832-11974T>C | Intron (SNP) | VAF 125/453 reads (28%) | called by muse, mutect2, varscan2
- MAMSTR | c.59-47C>G | Intron (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- MED15 | c.1153-16C>T | Intron (SNP) | VAF 204/613 reads (33%) | called by muse, mutect2, varscan2
- PHF7 | c.680+20A>C | Intron (SNP) | VAF 202/938 reads (22%) | called by muse, mutect2, varscan2
- PLA1A | c.*60G>A | 3'UTR (SNP) | VAF 90/355 reads (25%) | called by muse, mutect2, varscan2
- RBP1 | c.253-7258C>A | Intron (SNP) | VAF 143/539 reads (27%) | called by muse, mutect2, varscan2
- SCMH1 | c.-471A>C | 5'UTR (SNP) | VAF 161/545 reads (30%) | called by muse, mutect2, varscan2
- STMP1 | c.*54C>T | 3'UTR (SNP) | VAF 80/517 reads (15%) | catalogued as rs1368526024; called by muse, mutect2, varscan2
- STXBP2 | c.326-10C>G | Intron (SNP) | VAF 61/273 reads (22%) | called by muse, mutect2, varscan2
- TBR1 | c.1191-33T>C | Intron (SNP) | VAF 35/101 reads (35%) | catalogued as rs1277979349; called by mutect2, varscan2
- VWDE | c.475+237C>G | Intron (SNP) | VAF 176/660 reads (27%) | called by muse, mutect2, varscan2
